Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A9UA, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A9UA-01A (Primary Tumor).

(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

Biopsy of uterine cervix:

- Poorly differentiated infiltrative squamous cell carcinoma.
- Angiolymphatic and perineural infiltrations not observed.

ICD-O-3

Carcinoma, squamous cell
NOS 8070/3

Site: Uterine Cervix NOS
C539

JL 3/7/14

Source: NCI Genomic Data Commons file 29841102-a225-40db-80fc-5ef589ad885f (TCGA-VS-A9UA.36B3C85C-699D-4C72-B0FD-45480AC0A41B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).